Surgical pathology report (de-identified scan), TCGA case TCGA-ZJ-AB0I, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site NCI HRE Branch, specimen TCGA-ZJ-AB0I-01A (Primary Tumor).

SPEC #: Status: Obtained: Received:

CLINICAL HISTORY:

ICD 9: 233.1

SPECIMEN/PROCEDURE:

1. CERVIX - BIOPSY

IMPRESSION:

CERVICAL BIOPSY AT 5 O'CLOCK:

Squamous cell carcinoma with stromal invasion, large cell keratinizing.

Dictated by:

Entered:

GROSS DESCRIPTION:

Received labeled with the patient's name and "cervical biopsy". Received are two pink to pale tan tissue fragments, ranging from 0.6 x 0.3 x 0.2 cm to 1.4 x 0.9 x 0.5 cm. The largest fragment is bisected. The specimens are entirely submitted in one cassette.

Dictated by:

Entered:

CPT Codes:

CERVICAL BIOPSY (1)/88305

ICD9 Codes:

180.9

Electronically Signed by: _____

ICD .0.3

Carcinoma, squamous cell, large cell
keratinizing NOS 8071/3
Site: Cervix NOS 0539
JH 6/8/14

** END OF REPORT **

Source: NCI Genomic Data Commons file 45c59474-91e2-4c18-8b44-d286b9de6d57 (TCGA-ZJ-AB0I.77538CA6-8ACB-4224-BF03-DC7A4BABCEF7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).